Surgical pathology report (de-identified scan), TCGA case TCGA-62-8394, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Thoraxklinik at University Hospital Heidelberg, specimen TCGA-62-8394-01A (Primary Tumor).

TSS Name: [REDACTED]

TSS Identifier: [REDACTED]

TSS Unique Patient #: [REDACTED]

Pathology Report-Summary:

Material:

lung, left: 19 x 16 x 6 cm

tumor, lower lobe: 2.0 x 2.0 x 2.5 cm

Diagnosis:

Adenocarcinoma, mixed subtype (partially: kribriiform, solid, micropapillary, BAC)

Infiltration of pleura visceralis

Lymphangiosis carcinomatosa

pT2, pN2 (21/33), pM1 (pericard), G3

Pathologist: [REDACTED]

Signature:

Date:

Source: NCI Genomic Data Commons file 7b03b979-8612-474c-a2a5-9adc0285252d (TCGA-62-8394.FFCAEA73-0146-4B42-AA1D-E032F6944E3D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).